Somatic mutation profile of tumor specimen TCGA-HT-7874-01A (aliquot TCGA-HT-7874-01A-11D-2395-08) from TCGA case TCGA-HT-7874, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 41.2 years (15,045 days).
Specimen TCGA-HT-7874-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 077c243a-d4a2-462d-ac2e-25e0fee9d200.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7874-10A (Blood Derived Normal), aliquot TCGA-HT-7874-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e0e12e0-58d7-4be8-bcac-54b069aee87b

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3128T>C p.M1043T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1057519937, COSV55900332; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAZ1B | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59994732; called by muse, mutect2, varscan2
- CBLL2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV60369891, COSV60370312; called by muse, mutect2, varscan2
- CCDC97 | c.865A>G p.M289V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs367824945; called by muse, mutect2, varscan2
- CYP4F3 | c.1373T>A p.F458Y | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV55409484, COSV55413712; called by muse, mutect2
- DGKK | c.2355T>G p.D785E | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV65709453; called by muse, mutect2, varscan2
- GAR1 | c.643A>G p.R215G | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV56994023; called by muse, mutect2
- HNRNPA0 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV59246955; called by muse, mutect2, varscan2
- IP6K3 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV53391948; called by muse, mutect2, varscan2
- KDR | c.2943G>C p.K981N | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV55776559; called by muse, mutect2, varscan2
- LIMK1 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV60284640; called by muse, mutect2, varscan2
- MROH2B | c.2906G>T p.R969I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV101270432, COSV68189609; called by muse, mutect2, varscan2
- NFATC2 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs781647966, COSV65358003; called by muse, mutect2
- PCDH19 | c.986A>G p.H329R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55271667; called by muse, mutect2, varscan2
- PCDHA3 | c.996T>G p.D332E | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV63546204; called by muse, mutect2, varscan2
- PRKCG | c.738C>G p.D246E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV54733165; called by muse, mutect2
- REPS1 | c.2152G>C p.D718H (on ENST00000450536 / NM_001286611.2; = p.D717H on NM_031922.4) | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV57813978; called by muse, mutect2
- SAMM50 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.212); catalogued as COSV63110678; called by muse, mutect2
- UGT2B11 | c.1193A>G p.D398G | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV71424424; called by muse, mutect2
- SHROOM4 | c.1388dup p.T464Yfs*6 | Frame Shift Ins (INS) | VAF 14/135 reads (10%) | called by mutect2, pindel
- CCDC88B | c.2382G>A p.R794= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV57268360; called by muse, mutect2
- CLCA2 | c.2226C>T p.S742= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV65288798; called by muse, mutect2
- EP400 | c.1740G>A p.Q580= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV57786694; called by muse, mutect2, varscan2
- HFE | c.1014C>T p.A338= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100352646; called by muse, mutect2, varscan2
- MYOF | c.5859C>T p.Y1953= | Silent (SNP) | VAF 31/528 reads (6%) | catalogued as rs192250227, COSV63710801; called by muse, mutect2
- RTL3 | c.723T>A p.T241= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV58185942; called by muse, mutect2, varscan2
